Somatic mutation profile of tumor specimen MP2PRT-PAVWIS-TBP1-A (aliquot MP2PRT-PAVWIS-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVWIS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,277 days).
Specimen MP2PRT-PAVWIS-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61a08993-b8c6-4de0-b999-c6106d49fb59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWIS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWIS-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ff7d852-0bb1-4f67-8c6e-907025f07132

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 21, Silent 9, Translation Start Site 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB4 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs776347334, COSV61460793; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATG7 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61614907; called by muse, mutect2, varscan2
- MPND | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 25/561 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.941); catalogued as rs1198939538; called by muse, mutect2
- PDZD8 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 114/440 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV57827135; called by muse, mutect2, varscan2
- PPFIA2 | c.1589A>G p.D530G | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1476105313; called by muse, mutect2, varscan2
- PTK6 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 26/872 reads (3%) | SIFT tolerated (0.96); PolyPhen benign (0.019); catalogued as rs1429070092, COSV99420934; called by muse, mutect2
- RNF115 | c.159C>T p.S53= | Splice Region (SNP) | VAF 19/135 reads (14%) | catalogued as rs1553718525; called by muse, mutect2, varscan2
- THADA | c.3947G>A p.R1316H | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as rs200421057, COSV57691243; called by muse, mutect2, varscan2
- AP2A2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 122/558 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- C1QTNF1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 141/505 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CELF4 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 108/362 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- CHD9 | c.4175T>C p.I1392T | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COL9A1 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.415); called by muse, varscan2
- FAT3 | c.4835A>C p.N1612T | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- GAD2 | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 17/663 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- IGHV1-69 | chr14:106714676 ACTGTGTCT>CC | Missense Mutation (DEL) | VAF 20/137 reads (15%) | called by pindel, varscan2*
- IGHV3-53 | c.337_346delinsCATACTGTGCGGGGG p.Y113Hfs*? | Frame Shift Ins (INS) | VAF 14/136 reads (10%) | called by pindel, varscan2*
- KREMEN2 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 88/381 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- MARF1 | c.564C>A p.C188* | Nonsense Mutation (SNP) | VAF 168/633 reads (27%) | called by muse, mutect2, varscan2
- NCOR1 | c.5079C>A p.Y1693* | Nonsense Mutation (SNP) | VAF 68/282 reads (24%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 233/2104 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4C | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 95/433 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SMC1B | c.1832T>G p.F611C | Missense Mutation (SNP) | VAF 103/441 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUSD3 | c.430G>C p.A144P | Missense Mutation (SNP) | VAF 10/283 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by muse, mutect2
- TPTE | c.449G>T p.R150I (on ENST00000618007 / NM_199261.4; = p.R132I on NM_199259.4) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTN | c.41377A>C p.K13793Q (on ENST00000591111; = p.K6369Q on NM_003319.4) | Missense Mutation (SNP) | VAF 79/212 reads (37%) | PolyPhen benign (0.018); called by muse, mutect2, varscan2
- UGGT1 | c.1555A>C p.M519L | Missense Mutation (SNP) | VAF 83/322 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANK3 | c.5748C>T p.T1916= | Silent (SNP) | VAF 22/439 reads (5%) | catalogued as rs146335871; called by muse, mutect2
- COL6A2 | c.408C>T p.C136= | Silent (SNP) | VAF 185/734 reads (25%) | catalogued as rs745970130; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.3210G>A p.E1070= (on ENST00000409039; = p.E1009= on NM_207437.3) | Silent (SNP) | VAF 91/293 reads (31%) | catalogued as COSV101292330; called by muse, mutect2, varscan2
- FEZF1 | c.315G>A p.A105= | Silent (SNP) | VAF 145/704 reads (21%) | called by muse, mutect2, varscan2
- KCND2 | c.45G>A p.A15= | Silent (SNP) | VAF 144/582 reads (25%) | catalogued as COSV58602125; called by muse, mutect2, varscan2
- KLC4 | c.130C>T p.L44= | Silent (SNP) | VAF 164/506 reads (32%) | called by muse, mutect2, varscan2
- MTOR | c.5589G>C p.S1863= | Silent (SNP) | VAF 143/499 reads (29%) | called by muse, mutect2, varscan2
- TLE4 | c.1512G>A p.T504= | Silent (SNP) | VAF 92/436 reads (21%) | catalogued as rs369501632, COSV99513119; called by muse, varscan2
- ZBED8 | c.750A>C p.G250= | Silent (SNP) | VAF 82/338 reads (24%) | called by muse, mutect2, varscan2
